Somatic mutation profile of tumor specimen TCGA-21-A5DI-01A (aliquot TCGA-21-A5DI-01A-31D-A26M-08) from TCGA case TCGA-21-A5DI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,374 days).
Specimen TCGA-21-A5DI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28359c41-11ef-49fa-8492-908f1ae94f71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-A5DI-10A (Blood Derived Normal), aliquot TCGA-21-A5DI-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b0cc3f6-f655-432b-9858-393c4474e83a

The open-access MAF lists 159 somatic variants for this specimen: 115 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 39, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, RNA 3, 3'UTR 2, Splice Region 2, Nonstop Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 59/142 reads (42%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV99258285; called by muse, mutect2, varscan2
- ABL2 | c.2927G>T p.R976L (on ENST00000502732 / NM_007314.4; = p.R961L on NM_005158.5) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1334335439, COSV100773108; called by muse, mutect2, varscan2
- ADAM23 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV100009153, COSV52233454; called by muse, mutect2, varscan2
- AHI1 | c.2970A>G p.I990M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.401); catalogued as COSV99664020; called by muse, mutect2
- AKAP17A | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs756475564, COSV100002567; called by muse, mutect2, varscan2
- ALCAM | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100065983; called by muse, mutect2, varscan2
- ALOX15 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53396948; called by muse, mutect2, varscan2
- ASPRV1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100208683; called by muse, mutect2
- ASTN2 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV100525540; called by muse, mutect2, varscan2
- ATP5F1A | c.1504A>G p.S502G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV99959243; called by muse, mutect2, varscan2
- ATP8B1 | c.2759T>G p.M920R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99378035; called by muse, mutect2, varscan2
- C10orf71 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100110757; called by muse, mutect2, varscan2
- C12orf40 | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100210917; called by muse, mutect2, varscan2
- C4orf19 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99448827; called by muse, mutect2, varscan2
- CASR | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as CD165750, COSV56136329; called by muse, mutect2
- CCDC73 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs1353661015, COSV100068329; called by muse, mutect2
- CD248 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as rs780617204, COSV100256821; called by muse, mutect2, varscan2
- CFAP69 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100290529; called by muse, mutect2, varscan2
- CHD7 | c.3302G>T p.C1101F | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as CM060925, COSV101418587; called by muse, mutect2, varscan2
- CMYA5 | c.5050G>C p.E1684Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV101484455, COSV71405752; called by muse, mutect2, varscan2
- CPQ | c.98T>A p.F33Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV99615601; called by muse, mutect2, varscan2
- CRYBG1 | c.5817C>G p.F1939L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV100954644; called by muse, mutect2
- CSMD2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596972; called by muse, mutect2
- DHX15 | c.1816G>C p.A606P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.723); catalogued as COSV100391849; called by muse, mutect2, varscan2
- DIP2C | c.1472A>T p.N491I | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99794159; called by muse, mutect2, varscan2
- DNAH2 | c.4255G>C p.V1419L | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV101209654; called by muse, mutect2, varscan2
- DPYSL5 | c.1299C>A p.H433Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV56515377, COSV99982915; called by muse, mutect2, varscan2
- DZIP3 | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100848131; called by muse, mutect2, varscan2
- ECPAS | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV99399557; called by muse, mutect2, varscan2
- EFCAB14 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV100905680; called by muse, mutect2
- EHMT1 | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100604428; called by muse, mutect2
- ELMO3 | c.1684C>T p.R562W (on ENST00000652269; = p.R509W on NM_024712.5) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944999898, COSV100441039; called by muse, mutect2, varscan2
- ELOA | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as COSV101403866; called by muse, mutect2, varscan2
- EOMES | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99842429; called by muse, mutect2, varscan2
- EPHA6 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101066146; called by muse, mutect2, varscan2
- EPHB3 | c.2354A>G p.D785G | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV100383347; called by muse, mutect2, varscan2
- EVX2 | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs747901985, COSV100420873; called by muse, mutect2, varscan2
- FAM135B | c.4221G>T p.*1407Yext*3 | Nonstop Mutation (SNP) | VAF 18/237 reads (8%) | catalogued as COSV99428657; called by muse, mutect2
- FAM47C | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs370862889, COSV63724891; called by muse, mutect2, varscan2
- FBRS | c.1127G>T p.R376L (on ENST00000287468; = p.R896L on NM_001105079.3) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV54916414, COSV99789442; called by muse, mutect2
- FBXO21 | c.1880A>C p.D627A (on ENST00000330622 / NM_033624.3; = p.D620A on NM_015002.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV100401907; called by muse, mutect2, varscan2
- FCRL4 | c.1136-1G>C p.X379_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99620634; called by muse, mutect2
- FLAD1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99423227; called by muse, mutect2
- FLT4 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs369974304, COSV56116683; called by muse, mutect2, varscan2
- FOXD4L4 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1352695536; called by mutect2, varscan2
- GBP3 | c.461C>G p.S154* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99352309, COSV99352811; called by muse, mutect2, varscan2
- GLYATL2 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1007437776, COSV99780592; called by muse, mutect2, varscan2
- GRID2 | c.1979G>C p.R660P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99939417, COSV99948298; called by muse, mutect2, varscan2
- GRM5 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as COSV100555021, COSV59605587; called by muse, mutect2, varscan2
- H3C7 | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99769320; called by muse, mutect2
- HCN1 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV57491871; called by muse, mutect2, varscan2
- HOMER2 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100420672; called by muse, mutect2, varscan2
- IREB2 | c.2287A>G p.R763G | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV99359828; called by muse, mutect2
- ITGB5 | c.1019dup p.N340Kfs*34 | Frame Shift Ins (INS) | VAF 19/165 reads (12%) | catalogued as rs763839738; called by mutect2, pindel, varscan2
- KMT2A | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100629321, COSV100630215, COSV63292308; called by muse, mutect2, varscan2
- LAMA1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101058032; called by muse, mutect2, varscan2
- LARP4 | c.1007A>T p.E336V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99529795; called by muse, mutect2, varscan2
- LILRB3 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV99558756; called by muse, mutect2, varscan2
- LRRC3B | c.235A>C p.I79L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV101186087; called by muse, mutect2, varscan2
- LSAMP | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100373328; called by muse, mutect2, varscan2
- LSM8 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50800748; called by muse, mutect2, varscan2
- MAST1 | c.3380C>T p.S1127L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99263935; called by muse, mutect2, varscan2
- MKX | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101008905; called by muse, mutect2, varscan2
- MSLN | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV101242433; called by muse, mutect2, varscan2
- MYH1 | c.4724A>G p.E1575G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV99877201; called by muse, mutect2, varscan2
- MYH2 | c.3041A>G p.D1014G | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV99821204; called by muse, mutect2, varscan2
- N4BP1 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs777869490, COSV99285695; called by muse, mutect2, varscan2
- NSUN3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1243055975, COSV100113523; called by muse, mutect2, varscan2
- OR1J4 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs970754670, COSV100534347; called by muse, mutect2, varscan2
- OR52A1 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV61092300; called by muse, mutect2, varscan2
- OR52B4 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101281621; called by muse, mutect2, varscan2
- OR5M10 | c.636C>G p.F212L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101595934; called by muse, mutect2, varscan2
- PCLO | c.10034A>C p.E3345A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100439362; called by muse, mutect2, varscan2
- PDE5A | c.1812G>C p.K604N | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV53347785, COSV99309381; called by muse, mutect2, varscan2
- PDE6A | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV99678830; called by muse, mutect2, varscan2
- PDHA2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV54782413; called by muse, mutect2
- PKD1L1 | c.2047G>C p.G683R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99221751; called by muse, mutect2, varscan2
- POR | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115798; called by muse, mutect2, varscan2
- POTEE | c.2527T>C p.Y843H | Missense Mutation (SNP) | VAF 73/440 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1361908387, COSV100389311; called by muse, mutect2, varscan2
- PTCH1 | c.2197T>C p.S733P | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100110362; called by muse, mutect2, varscan2
- PTCHD4 | c.633A>T p.E211D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100261963; called by muse, mutect2, varscan2
- PTPRO | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs773532368, COSV55506780, COSV55521908; called by muse, mutect2, varscan2
- RASA1 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99171456; called by muse, mutect2, varscan2
- RNF114 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449836607, COSV54870473, COSV99724926; called by muse, mutect2, varscan2
- ROBO3 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.208); catalogued as COSV101185242, COSV67299625; called by muse, mutect2
- RXFP1 | c.1784T>C p.I595T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100314331; called by muse, mutect2, varscan2
- SALL1 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as rs755484949, COSV99171577, COSV99192553; called by muse, mutect2, varscan2
- SLC7A11 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99763046, COSV99763602; called by muse, varscan2
- SLCO1B1 | c.311T>A p.M104K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258500103, COSV57019750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNPH | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.379); catalogued as COSV100378475; called by muse, mutect2, varscan2
- SORCS1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs569730754, COSV99551305; called by muse, mutect2, varscan2
- SPATA6 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100893463; called by muse, mutect2, varscan2
- STKLD1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100912248; called by muse, mutect2
- TG | c.4079A>T p.E1360V | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99603908; called by muse, mutect2, varscan2
- TMEM74 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV52465048, COSV99866032; called by muse, mutect2, varscan2
- TRAPPC12 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs759458791, COSV100161080; called by muse, mutect2
- TTN | c.48022G>A p.A16008T (on ENST00000591111; = p.A8584T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | PolyPhen benign (0.073); catalogued as COSV100635424; called by muse, mutect2, varscan2
- TULP4 | c.4511G>T p.R1504L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100893910, COSV65578602; called by muse, mutect2
- UBA1 | c.3110A>T p.E1037V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100255636, COSV100256216; called by muse, mutect2, varscan2
- USP47 | c.1841T>C p.L614S (on ENST00000399455 / NM_001372095.1; = p.L526S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100360064; called by muse, varscan2
- VARS1 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV100791872; called by muse, mutect2
- ZIM3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.568); catalogued as COSV54141468; called by muse, mutect2, varscan2
- ZNF660 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV100502896; called by muse, mutect2, varscan2
- ATXN7L2 | c.1992dup p.E665* | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- BTN2A3P | n.82C>T | Splice Region (SNP) | VAF 12/50 reads (24%) | called by muse, varscan2
- CBLN1 | c.370del p.R124Dfs*6 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.1213del p.I405* | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- IQCG | c.511_512insTA p.D171Vfs*9 | Frame Shift Ins (INS) | VAF 19/273 reads (7%) | called by mutect2, pindel*
- LILRA6 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- MAGEB6B | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MRC1 | c.3250G>T p.D1084Y | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PLCB4 | c.3513_*5del | Nonstop Mutation (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel
- RAPGEF2 | c.1459del p.H487Tfs*21 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- TPBG | c.348_366del p.L117Sfs*56 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- ACSL1 | c.1530G>T p.V510= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99861059; called by muse, mutect2, varscan2
- AKAP3 | c.1866T>A p.V622= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as COSV99962714; called by muse, mutect2, varscan2
- ARHGEF28 | c.708A>G p.E236= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs533509301, COSV99710439; called by muse, mutect2, varscan2
- ASB2 | c.1704A>G p.L568= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100279668; called by muse, mutect2, varscan2
- C1orf100 | c.390C>G p.L130= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV100353534; called by muse, mutect2
- CCDC80 | c.225G>A p.Q75= | Silent (SNP) | VAF 83/194 reads (43%) | catalogued as COSV99245444; called by muse, mutect2, varscan2
- CSMD2 | c.1242C>T p.G414= | Silent (SNP) | VAF 20/209 reads (10%) | catalogued as COSV99596970; called by muse, mutect2
- FBH1 | c.2478C>T p.T826= (on ENST00000362091 / NM_178150.3; = p.T877= on NM_032807.4) | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs144492007; called by muse, mutect2, varscan2
- GBP4 | c.942T>C p.Y314= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs371314987, COSV100864494; called by muse, mutect2, varscan2
- GLP2R | c.582C>T p.F194= | Silent (SNP) | VAF 134/335 reads (40%) | catalogued as COSV99302617; called by muse, mutect2, varscan2
- GPA33 | c.303C>T p.S101= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100901323; called by muse, mutect2, varscan2
- GRHL2 | c.192C>T p.L64= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs746434474, COSV52555881, COSV99307854; called by muse, mutect2, varscan2
- HECTD4 | c.8958A>T p.P2986= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101108435; called by muse, mutect2
- IL19 | c.300C>A p.I100= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as COSV54284646, COSV99536518; called by muse, mutect2, varscan2
- KCMF1 | c.750C>T p.T250= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs372803630; called by muse, mutect2, varscan2
- KRTAP10-5 | c.117G>C p.L39= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as COSV100555939; called by muse, mutect2, varscan2
- LRRIQ4 | c.273G>C p.G91= | Silent (SNP) | VAF 46/233 reads (20%) | catalogued as COSV100540441; called by muse, mutect2, varscan2
- MAP4K4 | c.3069T>C p.C1023= (on ENST00000347699 / NM_001242559.2; = p.C941= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs1340319740, COSV100156178; called by muse, mutect2
- MKNK1 | c.147C>T p.A49= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100361584; called by muse, mutect2
- MUC17 | c.7497T>A p.T2499= | Silent (SNP) | VAF 120/505 reads (24%) | catalogued as COSV100075584; called by muse, mutect2, varscan2
- NFASC | c.2151C>T p.S717= (on ENST00000339876 / NM_001378329.1; = p.S713= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/249 reads (12%) | catalogued as rs776480436, COSV100362452; called by muse, mutect2, varscan2
- NLRC5 | c.4008G>A p.R1336= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV52660098, COSV52663731; called by muse, mutect2
- NRN1 | c.13T>C p.L5= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV99784322; called by muse, mutect2, varscan2
- OR2T12 | c.105C>A p.T35= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100528065; called by muse, mutect2, varscan2
- OR2T34 | c.573G>A p.K191= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as rs768806866, COSV100170598; called by muse, mutect2, varscan2
- OR5D13 | c.153C>A p.I51= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs755794704, COSV100687007, COSV100687126; called by muse, mutect2, varscan2
- PRELID3A | c.375A>G p.T125= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100427030; called by muse, mutect2, varscan2
- PRKD1 | c.2601G>C p.L867= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100121835, COSV100121976; called by muse, mutect2, varscan2
- PRKD2 | c.336C>A p.S112= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99354732; called by muse, mutect2, varscan2
- RFPL2 | c.609C>T p.D203= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs753078382, COSV50710845; called by muse, mutect2, varscan2
- SAFB2 | c.504A>G p.A168= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99386167; called by muse, mutect2, varscan2
- SLC12A2 | c.846C>A p.V282= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99321694; called by muse, mutect2, varscan2
- STK19 | c.69G>C p.R23= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- TRIM2 | c.417G>A p.R139= (on ENST00000437508; = p.R166= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs917582222, COSV100108346; called by muse, mutect2, varscan2
- TRPS1 | c.696C>T p.Y232= (on ENST00000220888 / NM_001330599.2; = p.Y245= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs199888153; called by muse, mutect2
- TTC29 | c.682T>C p.L228= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100284784; called by muse, mutect2
- TTN | c.46074T>C p.D15358= (on ENST00000591111; = p.D7934= on NM_003319.4) | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs756222708, COSV100635428; called by muse, mutect2, varscan2
- WDR72 | c.408C>A p.V136= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs886051303, COSV100855241; called by muse, mutect2, varscan2
- ZNF566 | c.69G>A p.L23= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV101091661; called by muse, mutect2, varscan2
- BOD1 | c.*7G>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs374312963; called by muse, mutect2, varscan2
- CPLANE1 | c.*2849C>A | 3'UTR (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99952111; called by muse, mutect2
- MIR379 | n.16T>C | RNA (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- OR2W5 | n.967C>T | RNA (SNP) | VAF 19/171 reads (11%) | catalogued as rs374342591; called by muse, mutect2, varscan2
- SNORD116-16 | n.55G>A | RNA (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
